Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2ML, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2ML-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

M43. Previous melanoma (L) anterior chest (depth 3mm, level III, mit 6-8/mm2, epithelioid). Rx WEPC 5.1.95. Now metastatic melanoma (L) axilla.

SPECIMEN INFORMATION

(L) axillary contents.

MACROSCOPIC DESCRIPTION

"Left axillary contents". A piece of fatty tissue 150 x 130 x 90mm, with an attached piece of skeletal muscle 75 x 65 x 45mm. The specimen was dissected for lymph nodes.

- A. 1 lymph node.
- B. 2 lymph nodes.
- C. 1 lymph node.
- D. 1 lymph node.
- E. 1 lymph node.
- F. 1 lymph node.

G&H. Two sections through an obviously involved node, 38mm across.

- J. 1 lymph node.
- K. 1 lymph node.
- L. 1 lymph node.
- M. 2 lymph nodes.
- N. 3 lymph nodes.
- O. 2 lymph nodes.

P-W. One large fatty lymph node, 65mm across (fat trimmed).

X&Y. 1 lymph node.

Z. 1 lymph node.

AA. 1 lymph node.

AB. 2 lymph nodes.

AC. 2 lymph nodes.

AD. 1 lymph node.

AE. 1 lymph node.

AF. 1 lymph node.

AG. 1 lymph node.

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, ax. lymph

C17.3

fw 8/24/11

MICROSCOPIC REPORT

Metastatic malignant melanoma is present in 1 (one) of 30 nodes.

Printed

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

The tumour has an epithelioid cytomorphology, no pigment, mitotic rate 2/mm2.
There is a moderate lymphocytic infiltrate in the deposit.
No extranodal extension seen.

Electronic signature

Verified by:

DIAGNOSIS

(L) axillary dissection - Metastatic MALIGNANT MELANOMA (1/30).

SUMMARY / KEY WORDS

Axillary lymph node - Malignant melanoma, metastatic

Source: NCI Genomic Data Commons file a56fce18-2e0a-4cbd-b48c-05a2e79287d1 (TCGA-EE-A2ML.079D6017-ED18-4D0B-88DA-DD9CAD850454.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).